Gene-level copy-number profile of tumor specimen ALCH-B1OJ-TTP1-A from ALCHEMIST case ALCH-B1OJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,866 days).
Specimen ALCH-B1OJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f31bba1-3295-40dd-aaeb-aeaed286566e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/6a9b2702-6a28-4ff5-887a-e50a41781a71

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 7,978; copy number 2: 42,272; copy number 3: 6,484; copy number 4: 1,534; copy number 5: 98.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,147,591–132,257,969, 4 genes (within-gene range 0–2): ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B.
- chr4:68,509,441–68,517,647, 1 gene: UGT2B29P.
- chr7:76,972,679–77,004,308, 2 genes (within-gene range 0–2): AC114737.1, DTX2P1.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr10:47,689,707–47,999,791, 8 genes (within-gene range 0–1): SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C.
- chr11:48,880,111–48,902,181, 3 genes: AC027369.6, AC027369.3, AC027369.4.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr16:35,836,886–35,912,516, 4 genes: VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr19:24,033,401–27,646,483, 8 genes: AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 98 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–4,883,716, 95 genes, copy number 5 (broad region; genes not listed).
- chr21:37,337,382–37,526,358, 3 genes, copy number 5: AP001437.2, AP001437.1, DYRK1A.

Autosomal genes at a single copy (total copy number 1): 6,260. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
